Gene-level copy-number profile of tumor specimen ALCH-B2C2-TTP1-A from ALCHEMIST case ALCH-B2C2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.6 years (23,242 days).
Specimen ALCH-B2C2-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7677facf-1957-47ca-be6d-74a44ce2c0d5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2C2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/35ff2a0a-b416-4311-810b-9f09ab8a2535

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 385; copy number 2: 56,082; copy number 3: 1,805; copy number 4: 11; copy number 5: 5; copy number 6: 2; copy number 7: 1; copy number 19: 2; copy number 22: 4.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr2:23,507,043–23,524,344, 1 gene (within-gene range 0–1): AC011239.1.
- chr2:94,861,362–94,862,667, 1 gene: SOWAHCP5.
- chr2:130,139,287–130,190,729, 3 genes (within-gene range 0–2): CCDC74B, SMPD4, MZT2B.
- chr3:52,495,338–52,524,495, 1 gene (within-gene range 0–2): STAB1.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr7:99,558,695–99,611,045, 2 genes (within-gene range 0–2): AC005020.2, TMEM225B.
- chr7:128,264,526–128,264,889, 1 gene: AC018635.2.
- chr8:12,356,136–12,359,391, 1 gene: ZNF705CP.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:96,019,724–96,027,993, 1 gene: LINC00092.
- chr10:50,676,743–50,695,981, 2 genes: NUTM2HP, AL589794.1.
- chr11:119,608,423–119,729,200, 4 genes (within-gene range 0–2): AP003393.1, NECTIN1, RNU6-1123P, NECTIN1-AS1.
- chr11:128,934,731–128,943,399, 1 gene: TP53AIP1.
- chr12:59,523,278–59,524,184, 1 gene: LINC02448.
- chr15:25,135,642–25,204,438, 22 genes (within-gene range 0–2): PWAR1, SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19.
- chr15:25,237,986–25,250,940, 8 genes (within-gene range 0–2): SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,828,095–41,899,528, 6 genes (within-gene range 0–2): JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1.
- chr15:74,411,357–74,411,432, 1 gene (within-gene range 0–2): MIR6881.
- chr15:88,252,730–88,271,066, 1 gene (within-gene range 0–2): NTRK3-AS1.
- chr17:17,810,399–17,837,011, 3 genes (within-gene range 0–1): SREBF1, MIR6777, MIR33B.
- chr17:49,210,411–49,230,787, 2 genes (within-gene range 0–2): ABI3, PHOSPHO1.
- chr17:63,484,823–63,521,848, 2 genes (within-gene range 0–2): AC113554.1, ACE3P.
- chr17:63,928,740–63,932,336, 1 gene: CD79B.
- chr19:11,237,450–11,241,943, 1 gene (within-gene range 0–2): ANGPTL8.
- chr19:38,289,151–38,317,273, 5 genes (within-gene range 0–2): AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33.
- chr20:62,410,237–62,427,539, 1 gene: RBBP8NL.
- chr22:22,899,481–22,906,803, 4 genes: IGLJ2, IGLC2, IGLJ3, IGLC3.
- chr22:23,059,415–23,145,021, 4 genes (within-gene range 0–2): RSPH14, GNAZ, Metazoa_SRP, U7.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:144,012,280–144,047,114, 1 gene, copy number 6 (within-gene range 2–6): SPATC1.
- chr8:144,078,002–144,080,648, 3 genes, copy number 5: AC109322.1, EXOSC4, MIR6847.
- chr9:40,321,299–40,333,460, 2 genes, copy number 19: FAM95B1, BX664727.1.
- chr9:61,581,813–61,582,675, 1 gene, copy number 6: AL935212.3.
- chr19:11,203,628–11,216,168, 2 genes, copy number 5 (within-gene range 2–5): AC011472.1, AC011472.5.
- chr21:43,461,960–43,479,534, 1 gene, copy number 22 (within-gene range 4–22): LINC00313.
- chr21:44,133,610–44,210,114, 4 genes, copy number 7–22 (within-gene range 1–22): GATD3A, LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 385. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
